Somatic mutation profile of tumor specimen MP2PRT-PAVAFZ-TMP1-A (aliquot MP2PRT-PAVAFZ-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVAFZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (735 days).
Specimen MP2PRT-PAVAFZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c994e7d8-7187-488b-805c-a002568d709f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAFZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAFZ-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c0ff1db-f1c7-4ab8-96fe-ea7d557d215e

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- APC2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 171/456 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143064262; called by muse, mutect2, varscan2
- FBN3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 278/809 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs762037436; called by muse, mutect2
- DMWD | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 353/841 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL22A1 | c.6C>T p.A2= | Silent (SNP) | VAF 178/462 reads (39%) | catalogued as rs147567223; called by muse, mutect2, varscan2
- NDNF | c.1083G>A p.K361= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs772059769; called by muse, mutect2, varscan2
- SIPA1 | c.417A>G p.S139= | Silent (SNP) | VAF 297/670 reads (44%) | called by muse, mutect2, varscan2
- NBEA | c.7618-346T>C | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, varscan2
